Gene-level copy-number profile of tumor specimen TCGA-C5-A7XC-01A from TCGA case TCGA-C5-A7XC, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB1; Tumor grade: G2; Age at diagnosis: 26.8 years (9,776 days).
Specimen TCGA-C5-A7XC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.04472113-b3fd-42c0-bfe4-dd50133d9ad4.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-C5-A7XC-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/24e0fab8-34be-453b-88e0-58eef5cd9706

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 6,156; copy number 2: 40,008; copy number 3: 13,062; copy number 4: 21; copy number 5: 149; copy number 6: 85; copy number 8: 130; copy number 9: 9; copy number 11: 137; copy number 20: 61.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-C5-A7XC-01A-11D-A386-01): tumor purity 0.59, ploidy 2.11, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 571 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:41,122,907–41,426,504, 2 genes, copy number 5: RNU6-365P, AC090138.1.
- chr11:81,175,201–89,065,945, 122 genes, copy number 5 (broad region; genes not listed).
- chr11:99,020,949–104,609,498, 70 genes, copy number 9–20 (within-gene range 1–20) (broad region; genes not listed).
- chr19:8,374,373–14,942,448, 377 genes, copy number 5–11 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 6,156. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
